Somatic mutation profile of tumor specimen HCM-BROD-0643-C43-06A (aliquot HCM-BROD-0643-C43-06A-11D-A80U-36) from HCMI case HCM-BROD-0643-C43, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IV; Age at diagnosis: 53.6 years (19,588 days).
Specimen HCM-BROD-0643-C43-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 034db2ac-0fbc-46c5-bae6-330551c05d74.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-BROD-0643-C43-10A (Blood Derived Normal), aliquot HCM-BROD-0643-C43-10A-01D-A80U-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2866f2b0-9bfc-403d-85a9-023fa08a8207

The open-access MAF lists 292 somatic variants for this specimen: 180 protein-altering or splice-affecting, 104 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 162, Silent 104, Nonsense Mutation 8, Intron 5, Splice Region 4, Frame Shift Del 3, Splice Site 3, 5'UTR 1, 3'UTR 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.182A>G p.Q61R | Missense Mutation (SNP) | VAF 76/293 reads (26%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen benign (0.251); catalogued as rs11554290, COSV54736340, COSV54736624, COSV54738969, COSV54747786; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.839G>A p.R280K | Missense Mutation (SNP) | VAF 29/248 reads (12%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.925); catalogued as rs121912660, CM153865, CM993218, COSV52666248, COSV52677783, COSV52687987; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- ABCA7 | c.2332C>T p.R778W | Missense Mutation (SNP) | VAF 39/306 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.586); catalogued as rs751607281; called by muse, mutect2, varscan2
- ADAMTS12 | c.4519G>A p.E1507K | Missense Mutation (SNP) | VAF 24/305 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.031); catalogued as COSV61265705; called by muse, mutect2
- ADAMTS18 | c.1933G>A p.E645K | Missense Mutation (SNP) | VAF 44/341 reads (13%) | SIFT tolerated (0.77); PolyPhen benign (0); catalogued as rs868333047, COSV51411009, COSV99273813; called by muse, mutect2, varscan2
- ADGRG2 | c.310A>G p.K104E (on ENST00000379869 / NM_001079858.3; = p.K101E on NM_005756.4) | Missense Mutation (SNP) | VAF 43/161 reads (27%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.9); catalogued as COSV100491844; called by muse, mutect2
- ADH1C | c.797C>T p.S266L | Missense Mutation (SNP) | VAF 33/376 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as rs1005267020, COSV72463393; called by muse, mutect2
- AFF2 | c.781C>T p.P261S | Missense Mutation (SNP) | VAF 43/187 reads (23%) | SIFT tolerated (0.36); PolyPhen probably damaging (0.996); catalogued as rs886044832; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ALX4 | c.421G>A p.E141K | Missense Mutation (SNP) | VAF 37/301 reads (12%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.098); catalogued as rs959308498; called by muse, varscan2
- ANGPT1 | c.988C>T p.R330C | Missense Mutation (SNP) | VAF 29/251 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52433501; called by muse, mutect2, varscan2
- ANKRD52 | c.1208C>T p.S403L | Missense Mutation (SNP) | VAF 45/180 reads (25%) | SIFT tolerated (0.26); PolyPhen benign (0.001); catalogued as COSV57284491; called by muse, mutect2, varscan2
- ARMC4 | c.253G>A p.D85N | Missense Mutation (SNP) | VAF 18/168 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.067); catalogued as COSV53466824; called by muse, mutect2
- ASAH2 | c.998G>A p.G333E | Missense Mutation (SNP) | VAF 29/203 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.678); catalogued as rs1269772733; called by muse, mutect2, varscan2
- AZIN2 | c.298C>T p.Q100* | Nonsense Mutation (SNP) | VAF 71/239 reads (30%) | catalogued as COSV99613754; called by muse, mutect2, varscan2
- BNC2 | c.1375C>T p.H459Y | Missense Mutation (SNP) | VAF 39/213 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV66155565; called by muse, mutect2, varscan2
- BTBD11 | c.739G>A p.D247N | Missense Mutation (SNP) | VAF 131/447 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.077); catalogued as rs1319239871; called by muse, mutect2, varscan2
- C11orf24 | c.41C>T p.S14F | Missense Mutation (SNP) | VAF 47/556 reads (8%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.854); catalogued as rs973677614, COSV58505473; called by muse, mutect2
- C4orf19 | c.223G>A p.E75K | Missense Mutation (SNP) | VAF 38/292 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.958); catalogued as rs1560315176; called by muse, mutect2, varscan2
- CACNA2D4 | c.791G>A p.W264* | Nonsense Mutation (SNP) | VAF 39/258 reads (15%) | catalogued as COSV54950668; called by muse, mutect2, varscan2
- CC2D1B | c.1076C>T p.A359V | Missense Mutation (SNP) | VAF 37/262 reads (14%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as rs764549898; called by muse, mutect2, varscan2
- CDHR4 | c.862C>G p.R288G | Missense Mutation (SNP) | VAF 16/160 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.501); catalogued as COSV58526111; called by muse, mutect2, varscan2
- CENPJ | c.1622C>T p.P541L | Missense Mutation (SNP) | VAF 43/319 reads (13%) | SIFT tolerated (0.88); PolyPhen benign (0); catalogued as COSV101121505; called by muse, mutect2, varscan2
- CFHR4 | c.1592G>A p.G531E (on ENST00000367416 / NM_001201551.2; = p.G285E on NM_006684.5) | Missense Mutation (SNP) | VAF 5/104 reads (5%) | SIFT tolerated (0.27); PolyPhen benign (0.379); catalogued as COSV52224734; called by muse, mutect2
- CLSTN3 | c.1712C>T p.P571L | Missense Mutation (SNP) | VAF 48/278 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as rs1390323681; called by muse, mutect2, varscan2
- CUX1 | c.31-1G>A p.X11_splice (on ENST00000292535 / NM_181552.4; = p.X22_splice on NM_001913.5) | Splice Site (SNP) | VAF 20/120 reads (17%) | catalogued as COSV99473316; called by muse, mutect2, varscan2
- DEFB125 | c.142C>T p.L48F | Missense Mutation (SNP) | VAF 28/231 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66703291; called by muse, mutect2, varscan2
- DMBT1 | c.854G>A p.G285E | Missense Mutation (SNP) | VAF 46/503 reads (9%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as rs759038747, COSV57534000; called by muse, mutect2
- DNA2 | c.1801C>T p.P601S | Missense Mutation (SNP) | VAF 22/201 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs765257819; called by muse, mutect2, varscan2
- DNAH5 | c.7834C>T p.H2612Y | Missense Mutation (SNP) | VAF 26/230 reads (11%) | SIFT tolerated (0.12); PolyPhen benign (0.033); catalogued as rs1211787821; called by muse, mutect2, varscan2
- DNPEP | c.931G>A p.E311K | Missense Mutation (SNP) | VAF 26/254 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1346102382, COSV56111973; called by muse, mutect2
- EDN3 | c.53-1G>A p.X18_splice | Splice Site (SNP) | VAF 25/208 reads (12%) | catalogued as rs746083251, COSV61108409; called by muse, mutect2, varscan2
- EMSY | c.3166C>T p.P1056S | Missense Mutation (SNP) | VAF 57/445 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.996); catalogued as COSV58265056; called by muse, mutect2, varscan2
- ESRP1 | c.1438G>A p.V480I | Missense Mutation (SNP) | VAF 20/185 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs1169738720; called by muse, mutect2, varscan2
- FAM135B | c.2458G>A p.G820R | Missense Mutation (SNP) | VAF 53/282 reads (19%) | SIFT tolerated, low confidence (0.58); PolyPhen benign (0); catalogued as COSV52752187; called by muse, mutect2, varscan2
- FAM170B | c.481G>A p.D161N | Missense Mutation (SNP) | VAF 44/325 reads (14%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.852); catalogued as rs868477134, COSV61253906; called by muse, mutect2, varscan2
- FAM187A | c.91C>T p.P31S | Missense Mutation (SNP) | VAF 65/292 reads (22%) | SIFT tolerated (0.29); PolyPhen benign (0.024); catalogued as rs1268355141; called by muse, mutect2, varscan2
- FAM187A | c.1235C>T p.S412F | Missense Mutation (SNP) | VAF 46/167 reads (28%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as rs1283240535; called by muse, mutect2, varscan2
- FGA | c.1103G>A p.G368E | Missense Mutation (SNP) | VAF 40/360 reads (11%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.009); catalogued as rs746736351, COSV57393378; called by muse, mutect2
- FHL5 | c.808G>A p.E270K | Missense Mutation (SNP) | VAF 26/234 reads (11%) | SIFT tolerated (0.24); PolyPhen benign (0.038); catalogued as rs1449031326, COSV58736537; called by muse, mutect2
- FLG | c.1492G>A p.E498K | Missense Mutation (SNP) | VAF 45/352 reads (13%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.955); catalogued as rs370228326; called by muse, mutect2, varscan2
- FPR2 | c.332G>A p.G111E | Missense Mutation (SNP) | VAF 44/249 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.906); catalogued as COSV60671857; called by muse, varscan2
- FSD1 | c.1004G>A p.R335Q | Missense Mutation (SNP) | VAF 37/217 reads (17%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.863); catalogued as rs991859124, COSV55695183; called by muse, mutect2, varscan2
- GIMAP5 | c.695G>A p.R232K | Missense Mutation (SNP) | VAF 36/402 reads (9%) | SIFT tolerated (0.2); PolyPhen benign (0.144); catalogued as COSV57530633; called by muse, mutect2
- GIMAP7 | c.535G>A p.E179K | Missense Mutation (SNP) | VAF 47/371 reads (13%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.71); catalogued as COSV57958911; called by muse, mutect2, varscan2
- GYS2 | c.61G>A p.E21K | Missense Mutation (SNP) | VAF 53/261 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0.098); catalogued as COSV53924583, COSV53929660; called by muse, mutect2, varscan2
- HBE1 | c.212C>T p.S71F | Missense Mutation (SNP) | VAF 26/173 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.987); catalogued as COSV53079530; called by muse, mutect2, varscan2
- KCNJ15 | c.371C>T p.S124F | Missense Mutation (SNP) | VAF 26/265 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV60810936; called by muse, mutect2, varscan2
- KIF26B | c.1871C>T p.S624F | Missense Mutation (SNP) | VAF 75/529 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV63644957; called by muse, mutect2, varscan2
- KLK12 | c.595G>A p.D199N | Missense Mutation (SNP) | VAF 41/249 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1409744695; called by muse, mutect2, varscan2
- LATS2 | c.917C>T p.P306L | Missense Mutation (SNP) | VAF 41/344 reads (12%) | SIFT tolerated (0.08); PolyPhen benign (0.01); catalogued as rs748263686; called by muse, mutect2, varscan2
- LGALS16 | c.215G>A p.W72* | Nonsense Mutation (SNP) | VAF 32/205 reads (16%) | catalogued as rs567987381; called by muse, mutect2, varscan2
- LINGO2 | c.699C>G p.D233E | Missense Mutation (SNP) | VAF 48/263 reads (18%) | SIFT tolerated (0.12); PolyPhen benign (0.005); catalogued as rs757978828; called by muse, mutect2, varscan2
- LRP1B | c.7154G>A p.G2385E | Missense Mutation (SNP) | VAF 29/188 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.323); catalogued as COSV67186728; called by muse, mutect2, varscan2
- MEFV | c.955G>A p.E319K | Missense Mutation (SNP) | VAF 47/369 reads (13%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.696); catalogued as rs104895110, CM041800, COSV54826976; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MYOM2 | c.77G>A p.R26Q | Missense Mutation (SNP) | VAF 38/301 reads (13%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.888); catalogued as rs369374390, COSV100036318; called by muse, mutect2, varscan2
- OR10J3 | c.965C>T p.S322F | Missense Mutation (SNP) | VAF 61/212 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as COSV100171595, COSV59954087; called by muse, mutect2, varscan2
- OR5AK2 | c.710C>T p.S237F | Missense Mutation (SNP) | VAF 37/214 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.74); catalogued as COSV58804384; called by muse, mutect2, varscan2
- OR6C70 | c.40G>A p.G14R | Missense Mutation (SNP) | VAF 28/137 reads (20%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.32); catalogued as COSV59245411; called by muse, mutect2, varscan2
- OSBPL5 | c.1273C>T p.R425C | Missense Mutation (SNP) | VAF 30/302 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55145209; called by muse, mutect2, varscan2
- PCLO | c.7459C>T p.P2487S | Missense Mutation (SNP) | VAF 53/361 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.947); catalogued as COSV61658962; called by muse, mutect2, varscan2
- PIK3C2G | c.3836C>T p.S1279L (on ENST00000676171; = p.S1238L on NM_004570.5) | Missense Mutation (SNP) | VAF 89/343 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as rs935135637, COSV56800636, COSV56812711; called by muse, mutect2, varscan2
- PLA2G4E | c.1609G>A p.E537K | Missense Mutation (SNP) | VAF 31/193 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs756536759; called by muse, mutect2, varscan2
- PLCB4 | c.2286G>A p.V762= | Splice Region (SNP) | VAF 49/193 reads (25%) | catalogued as rs1018917845; called by muse, mutect2, varscan2
- PLXNA4 | c.143C>T p.A48V | Missense Mutation (SNP) | VAF 104/383 reads (27%) | SIFT tolerated (0.31); PolyPhen benign (0.04); catalogued as COSV58166450; called by muse, mutect2, varscan2
- PRKAA2 | c.832C>T p.P278S | Missense Mutation (SNP) | VAF 44/217 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64802460; called by muse, mutect2, varscan2
- PTPN13 | c.844C>T p.P282S | Missense Mutation (SNP) | VAF 17/276 reads (6%) | SIFT tolerated (0.46); PolyPhen benign (0.003); catalogued as rs1165333843; called by muse, mutect2
- PTPN13 | c.845C>T p.P282L | Missense Mutation (SNP) | VAF 18/276 reads (7%) | SIFT tolerated (0.96); PolyPhen benign (0); catalogued as rs368916880, COSV100364898; called by muse, mutect2
- RAVER2 | c.1148C>T p.P383L | Missense Mutation (SNP) | VAF 29/264 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.67); catalogued as rs1443350938; called by muse, mutect2, varscan2
- RFPL4B | c.715G>A p.E239K | Missense Mutation (SNP) | VAF 26/237 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.277); catalogued as COSV101480681; called by muse, mutect2, varscan2
- RGS7 | c.1147G>A p.E383K | Missense Mutation (SNP) | VAF 54/325 reads (17%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.768); catalogued as rs866505496, COSV58531455; called by muse, mutect2, varscan2
- RHAG | c.296G>A p.G99E | Missense Mutation (SNP) | VAF 33/281 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57702961; called by muse, mutect2, varscan2
- RYR1 | c.2095G>A p.E699K | Missense Mutation (SNP) | VAF 42/316 reads (13%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.991); catalogued as rs553882104, COSV62096141; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- S100Z | c.187G>A p.D63N | Missense Mutation (SNP) | VAF 37/185 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs373309306; called by muse, mutect2, varscan2
- SCN11A | c.4660G>A p.D1554N | Missense Mutation (SNP) | VAF 39/234 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV56565290; called by muse, mutect2, varscan2
- SEZ6L | c.1936G>A p.E646K | Missense Mutation (SNP) | VAF 38/304 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.131); catalogued as rs752901613, COSV50657778; called by muse, mutect2, varscan2
- SLC26A9 | c.1016C>T p.S339F | Missense Mutation (SNP) | VAF 39/362 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs755264562, COSV61602448; called by muse, mutect2, varscan2
- SLC27A6 | c.1703G>A p.G568E | Missense Mutation (SNP) | VAF 14/115 reads (12%) | SIFT tolerated (0.16); PolyPhen benign (0.049); catalogued as rs151144946; called by muse, varscan2
- SLC27A6 | c.1819G>A p.E607K | Missense Mutation (SNP) | VAF 15/108 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.105); catalogued as rs1315273250, COSV52482732; called by muse, varscan2
- SLC39A11 | c.509C>T p.P170L (on ENST00000542342 / NM_001159770.2; = p.P163L on NM_139177.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 56/469 reads (12%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as COSV55299911; called by muse, mutect2, varscan2
- SORCS3 | c.2989C>T p.H997Y | Missense Mutation (SNP) | VAF 15/181 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV100863767, COSV63796584; called by muse, mutect2
- SVEP1 | c.3338G>A p.G1113E | Missense Mutation (SNP) | VAF 17/128 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57028499; called by muse, mutect2, varscan2
- TAAR6 | c.918G>T p.M306I | Missense Mutation (SNP) | VAF 32/227 reads (14%) | SIFT tolerated (0.38); PolyPhen benign (0.006); catalogued as COSV99256622; called by muse, mutect2, varscan2
- TBC1D10C | c.115C>T p.R39C | Missense Mutation (SNP) | VAF 54/572 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.816); catalogued as rs371478822, COSV100408234; called by muse, mutect2
- TBC1D2 | c.2467C>T p.R823C | Missense Mutation (SNP) | VAF 24/211 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs376572846; called by muse, mutect2
- TBC1D21 | c.400C>T p.P134S | Missense Mutation (SNP) | VAF 35/239 reads (15%) | SIFT tolerated (0.48); PolyPhen benign (0.294); catalogued as COSV55995390; called by muse, mutect2, varscan2
- TRIOBP | c.2188C>T p.P730S | Missense Mutation (SNP) | VAF 51/370 reads (14%) | SIFT deleterious, low confidence (0.05); PolyPhen possibly damaging (0.476); catalogued as COSV60377658; called by muse, mutect2, varscan2
- TRPM7 | c.4055C>T p.S1352F | Missense Mutation (SNP) | VAF 29/242 reads (12%) | SIFT tolerated, low confidence (0.54); PolyPhen benign (0.058); catalogued as rs1316733265; called by muse, mutect2, varscan2
- TTN | c.68362G>A p.E22788K (on ENST00000591111; = p.E15364K on NM_003319.4) | Missense Mutation (SNP) | VAF 42/295 reads (14%) | PolyPhen probably damaging (0.994); catalogued as rs373773552; called by muse, mutect2, varscan2
- UBE2Z | c.733C>T p.R245W | Missense Mutation (SNP) | VAF 29/202 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.511); catalogued as rs1232589217; called by muse, mutect2, varscan2
- UHRF1 | c.1354C>T p.R452W (on ENST00000612630 / NM_001290050.1; = p.R465W on NM_013282.4) | Missense Mutation (SNP) | VAF 42/299 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1308222891; called by muse, mutect2, varscan2
- UNC13C | c.4304C>T p.P1435L | Missense Mutation (SNP) | VAF 24/213 reads (11%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.356); catalogued as COSV52899179; called by muse, mutect2, varscan2
- VGLL3 | c.749C>T p.P250L | Missense Mutation (SNP) | VAF 51/351 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as COSV101052111; called by muse, mutect2, varscan2
- ZGRF1 | c.5714G>A p.R1905Q | Missense Mutation (SNP) | VAF 28/215 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as rs574383993; called by muse, mutect2, varscan2
- ZNF780B | c.1541C>T p.S514L | Missense Mutation (SNP) | VAF 42/248 reads (17%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.99); catalogued as rs747559058; called by muse, mutect2, varscan2
- ACSM2A | c.1142G>A p.G381E (on ENST00000219054; = p.G302E on NM_001308169.2) | Missense Mutation (SNP) | VAF 29/198 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ACTL8 | c.766C>T p.P256S | Missense Mutation (SNP) | VAF 136/438 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- ACVR1C | c.817C>T p.H273Y | Missense Mutation (SNP) | VAF 20/248 reads (8%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.919); called by muse, mutect2
- ADH6 | c.50A>C p.K17T | Missense Mutation (SNP) | VAF 15/150 reads (10%) | SIFT tolerated (0.11); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- ANKRD2 | c.980C>T p.T327I | Missense Mutation (SNP) | VAF 43/330 reads (13%) | SIFT tolerated (0.37); PolyPhen probably damaging (0.946); called by muse, mutect2, varscan2
- ARHGAP11A | c.250G>A p.G84R | Missense Mutation (SNP) | VAF 38/278 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ARHGAP11A | c.251G>A p.G84E | Missense Mutation (SNP) | VAF 38/278 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ATG2A | c.3404C>T p.T1135I | Missense Mutation (SNP) | VAF 30/221 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- C10orf71 | c.3253G>A p.G1085R | Missense Mutation (SNP) | VAF 39/409 reads (10%) | SIFT tolerated (0.3); PolyPhen benign (0.017); called by muse, mutect2
- C18orf63 | c.1577C>T p.P526L | Missense Mutation (SNP) | VAF 24/220 reads (11%) | SIFT tolerated (0.14); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- C1orf116 | c.617A>G p.D206G | Missense Mutation (SNP) | VAF 40/370 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.943); called by muse, mutect2, varscan2
- CASKIN1 | c.244G>A p.G82S | Missense Mutation (SNP) | VAF 20/182 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CCDC114 | c.1895G>A p.G632E | Missense Mutation (SNP) | VAF 69/424 reads (16%) | SIFT tolerated (0.11); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- CDH12 | c.2371G>A p.D791N | Missense Mutation (SNP) | VAF 23/144 reads (16%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- CEP131 | c.268C>T p.P90S | Missense Mutation (SNP) | VAF 62/299 reads (21%) | SIFT tolerated (0.41); PolyPhen benign (0.288); called by muse, mutect2, varscan2
- CFAP251 | c.527G>A p.R176K | Missense Mutation (SNP) | VAF 54/208 reads (26%) | SIFT tolerated (0.44); PolyPhen benign (0); called by muse, mutect2, varscan2
- CFAP69 | c.1099A>G p.K367E | Missense Mutation (SNP) | VAF 11/108 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- CFTR | c.54-1G>A p.X18_splice | Splice Site (SNP) | VAF 19/187 reads (10%) | called by muse, mutect2
- CHRNA2 | c.1544G>A p.G515E | Missense Mutation (SNP) | VAF 30/236 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CSMD2 | c.1565G>A p.G522D | Missense Mutation (SNP) | VAF 30/289 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- DACH1 | c.1751C>T p.T584I (on ENST00000619232 / NM_001366712.1; = p.T330I on NM_004392.6) | Missense Mutation (SNP) | VAF 31/275 reads (11%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- DGCR8 | c.847C>T p.P283S | Missense Mutation (SNP) | VAF 35/247 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.048); called by muse, mutect2, varscan2
- EIF3G | c.646C>T p.P216S | Missense Mutation (SNP) | VAF 47/316 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- EPPK1 | c.2848A>C p.M950L | Missense Mutation (SNP) | VAF 36/325 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- FAM187A | c.92C>T p.P31L | Missense Mutation (SNP) | VAF 67/298 reads (22%) | SIFT tolerated (0.05); PolyPhen benign (0.212); called by muse, mutect2, varscan2
- FGD2 | c.1210G>A p.E404K | Missense Mutation (SNP) | VAF 46/299 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.492); called by muse, mutect2, varscan2
- FN1 | c.337G>T p.E113* | Nonsense Mutation (SNP) | VAF 24/246 reads (10%) | called by muse, mutect2, varscan2
- FZD2 | c.833G>A p.R278Q | Missense Mutation (SNP) | VAF 94/366 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- GLT1D1 | c.316G>A p.E106K | Missense Mutation (SNP) | VAF 36/184 reads (20%) | SIFT tolerated (0.28); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- GPX2 | c.136G>A p.D46N | Missense Mutation (SNP) | VAF 33/226 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- HLA-A | c.1081_1087del p.G361Mfs*29 (on ENST00000376806; = p.G355Mfs*29 on NM_002116.8) | Frame Shift Del (DEL) | VAF 16/89 reads (18%) | called by mutect2, pindel
- IFNAR2 | c.1511C>T p.S504L | Missense Mutation (SNP) | VAF 43/220 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.802); called by muse, mutect2, varscan2
- IFT122 | c.2591T>C p.I864T (on ENST00000348417 / NM_052989.3; = p.I805T on NM_018262.4) | Missense Mutation (SNP) | VAF 18/174 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.003); called by muse, mutect2
- ITGA2 | c.2695C>T p.L899F | Missense Mutation (SNP) | VAF 23/165 reads (14%) | SIFT tolerated (0.11); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- KBTBD13 | c.956C>T p.A319V | Missense Mutation (SNP) | VAF 51/353 reads (14%) | SIFT tolerated (0.36); PolyPhen benign (0); called by muse, mutect2, varscan2
- KLHDC7B | c.119G>A p.G40D (on ENST00000395676; = p.G681D on NM_138433.5) | Missense Mutation (SNP) | VAF 37/290 reads (13%) | SIFT tolerated, low confidence (0.52); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- MCHR2 | c.464T>C p.L155S | Missense Mutation (SNP) | VAF 36/230 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.648); called by muse, mutect2, varscan2
- MIS18BP1 | c.2290A>C p.K764Q | Missense Mutation (SNP) | VAF 50/228 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.231); called by muse, mutect2, varscan2
- MMP24 | c.1396G>A p.E466K | Missense Mutation (SNP) | VAF 82/335 reads (24%) | SIFT tolerated (0.11); PolyPhen benign (0.328); called by muse, mutect2, varscan2
- MUC16 | c.6926C>T p.P2309L | Missense Mutation (SNP) | VAF 22/206 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); called by muse, mutect2, varscan2
- MYBPC3 | c.657C>T p.V219= | Splice Region (SNP) | VAF 33/233 reads (14%) | called by muse, mutect2, varscan2
- NDST4 | c.1036C>T p.L346F | Missense Mutation (SNP) | VAF 25/226 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NT5C1B | c.120G>A p.Q40= | Splice Region (SNP) | VAF 31/204 reads (15%) | called by muse, mutect2, varscan2
- PCLO | c.13834G>A p.D4612N | Missense Mutation (SNP) | VAF 16/179 reads (9%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.677); called by muse, mutect2, varscan2
- PPP1R42 | c.194T>G p.I65S | Missense Mutation (SNP) | VAF 20/218 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.774); called by muse, mutect2
- PRAMEF2 | c.274A>G p.K92E | Missense Mutation (SNP) | VAF 64/207 reads (31%) | SIFT tolerated (0.33); PolyPhen benign (0.16); called by muse, mutect2, varscan2
- PRDM9 | c.853G>A p.E285K | Missense Mutation (SNP) | VAF 28/233 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- PROKR1 | c.586C>T p.P196S | Missense Mutation (SNP) | VAF 40/318 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PROX2 | c.143C>T p.S48F | Missense Mutation (SNP) | VAF 41/328 reads (13%) | SIFT tolerated (0.11); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- RAPGEF3 | c.428G>A p.G143E (on ENST00000389212; = p.G101E on NM_006105.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 78/252 reads (31%) | SIFT tolerated (0.2); PolyPhen benign (0.354); called by muse, mutect2, varscan2
- RAPGEF3 | c.427G>A p.G143R (on ENST00000389212; = p.G101R on NM_006105.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 78/252 reads (31%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.901); called by muse, mutect2, varscan2
- RAPGEF5 | c.1723A>T p.R575W (on ENST00000401957 / NM_001367602.2; = p.R878W on NM_012294.5) | Missense Mutation (SNP) | VAF 23/207 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); called by muse, mutect2, varscan2
- RAVER2 | c.1147C>T p.P383S | Missense Mutation (SNP) | VAF 29/263 reads (11%) | SIFT tolerated (0.14); PolyPhen benign (0.123); called by muse, mutect2, varscan2
- RNF17 | c.2284G>A p.D762N | Missense Mutation (SNP) | VAF 16/152 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RPS6KB2 | c.880C>A p.P294T | Missense Mutation (SNP) | VAF 35/445 reads (8%) | SIFT tolerated (0.19); PolyPhen benign (0.065); called by muse, mutect2
- RTL3 | c.709C>T p.P237S | Missense Mutation (SNP) | VAF 53/184 reads (29%) | SIFT tolerated (0.33); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- RTL3 | c.520C>T p.Q174* | Nonsense Mutation (SNP) | VAF 55/181 reads (30%) | called by muse, mutect2, varscan2
- SCN2A | c.2353G>A p.E785K | Missense Mutation (SNP) | VAF 22/250 reads (9%) | SIFT tolerated (0.31); PolyPhen benign (0); called by muse, mutect2
- SEC14L2 | c.943G>A p.G315S | Missense Mutation (SNP) | VAF 27/159 reads (17%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.586); called by muse, mutect2, varscan2
- SEC16B | c.1137C>T p.S379= | Splice Region (SNP) | VAF 28/154 reads (18%) | called by muse, mutect2, varscan2
- SIK2 | c.1055_1068del p.G352Afs*2 | Frame Shift Del (DEL) | VAF 22/216 reads (10%) | called by mutect2, pindel
- SLK | c.494T>C p.L165S | Missense Mutation (SNP) | VAF 18/175 reads (10%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.998); called by muse, mutect2
- SMYD2 | c.95T>A p.L32* | Nonsense Mutation (SNP) | VAF 106/440 reads (24%) | called by muse, varscan2
- SPTBN4 | c.6689G>A p.R2230Q | Missense Mutation (SNP) | VAF 77/523 reads (15%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- STAMBPL1 | c.373C>T p.L125F | Missense Mutation (SNP) | VAF 14/152 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- SYNCRIP | c.691G>A p.G231R | Missense Mutation (SNP) | VAF 19/200 reads (10%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.95); called by muse, mutect2
- TENM1 | c.1788C>A p.C596* | Nonsense Mutation (SNP) | VAF 58/246 reads (24%) | called by muse, mutect2, varscan2
- TFCP2L1 | c.424G>A p.D142N | Missense Mutation (SNP) | VAF 35/256 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.882); called by muse, mutect2, varscan2
- TMEM87A | c.886C>T p.L296F | Missense Mutation (SNP) | VAF 19/202 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.031); called by muse, mutect2
- TMPRSS4 | c.1204G>A p.G402S | Missense Mutation (SNP) | VAF 45/301 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TOP2B | c.1418C>T p.S473F (on ENST00000264331 / NM_001330700.2; = p.S468F on NM_001068.3) | Missense Mutation (SNP) | VAF 28/195 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.72); called by muse, mutect2, varscan2
- TRAV9-1 | c.50G>A p.G17E | Missense Mutation (SNP) | VAF 18/230 reads (8%) | SIFT tolerated (0.9); PolyPhen benign (0.03); called by muse, mutect2
- TSPEAR | c.1555C>T p.Q519* | Nonsense Mutation (SNP) | VAF 54/201 reads (27%) | called by muse, mutect2, varscan2
- TSPOAP1 | c.5128C>T p.P1710S | Missense Mutation (SNP) | VAF 27/302 reads (9%) | SIFT tolerated (0.09); PolyPhen benign (0.254); called by muse, mutect2
- TXNDC5 | c.1024T>C p.F342L | Missense Mutation (SNP) | VAF 36/260 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.962); called by muse, mutect2
- UNC45B | c.1226C>T p.P409L | Missense Mutation (SNP) | VAF 30/388 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- VPS9D1 | c.902C>T p.P301L | Missense Mutation (SNP) | VAF 75/495 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- WDR47 | c.2525C>T p.S842F (on ENST00000369962 / NM_001142551.2; = p.S843F on NM_014969.5) | Missense Mutation (SNP) | VAF 42/316 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.58); called by muse, mutect2, varscan2
- XPR1 | c.464G>A p.G155E | Missense Mutation (SNP) | VAF 23/263 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- ZFPM2 | c.1940C>T p.S647F | Missense Mutation (SNP) | VAF 43/305 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.133); called by muse, mutect2, varscan2
- ZFYVE27 | c.383A>T p.H128L | Missense Mutation (SNP) | VAF 31/257 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.086); called by muse, mutect2, varscan2
- ZNF316 | c.2013del p.I672Sfs*119 | Frame Shift Del (DEL) | VAF 42/224 reads (19%) | called by mutect2, pindel*, varscan2
- ZNF527 | c.470C>T p.S157F | Missense Mutation (SNP) | VAF 28/230 reads (12%) | SIFT tolerated (0.7); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ZNF536 | c.2123G>A p.G708E | Missense Mutation (SNP) | VAF 52/409 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZNF808 | c.1109C>T p.P370L | Missense Mutation (SNP) | VAF 28/185 reads (15%) | SIFT tolerated (0.08); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZNF827 | c.1535A>C p.Q512P | Missense Mutation (SNP) | VAF 60/325 reads (18%) | SIFT tolerated (0.17); PolyPhen benign (0); called by muse, mutect2, varscan2
- ABL1 | c.2493C>T p.P831= | Silent (SNP) | VAF 44/296 reads (15%) | catalogued as COSV59335628; called by muse, mutect2, varscan2
- ADGRG6 | c.3357G>A p.E1119= | Silent (SNP) | VAF 19/176 reads (11%) | called by muse, mutect2, varscan2
- ARHGAP15 | c.288G>A p.K96= | Silent (SNP) | VAF 23/182 reads (13%) | called by muse, mutect2, varscan2
- AZIN2 | c.297C>T p.V99= | Silent (SNP) | VAF 71/235 reads (30%) | called by muse, mutect2, varscan2
- C11orf24 | c.42C>T p.S14= | Silent (SNP) | VAF 47/552 reads (9%) | called by muse, mutect2
- CACNA1E | c.3300G>A p.K1100= | Silent (SNP) | VAF 74/303 reads (24%) | catalogued as COSV62392622; called by muse, mutect2, varscan2
- CACNA1I | c.591C>T p.I197= | Silent (SNP) | VAF 28/197 reads (14%) | called by muse, mutect2, varscan2
- CCDC81 | c.1782G>A p.K594= (on ENST00000445632 / NM_001156474.2; = p.K504= on NM_021827.4) | Silent (SNP) | VAF 23/196 reads (12%) | called by muse, mutect2, varscan2
- CCN5 | c.747C>T p.A249= | Silent (SNP) | VAF 41/411 reads (10%) | called by muse, mutect2, varscan2
- CEP295 | c.4659C>T p.S1553= | Silent (SNP) | VAF 30/196 reads (15%) | catalogued as rs1200542669; called by muse, mutect2, varscan2
- CES3 | c.1308C>T p.V436= | Silent (SNP) | VAF 24/258 reads (9%) | called by muse, mutect2
- CFAP251 | c.528G>A p.R176= | Silent (SNP) | VAF 56/209 reads (27%) | called by muse, mutect2, varscan2
- CHRNA2 | c.1545G>A p.G515= | Silent (SNP) | VAF 29/235 reads (12%) | catalogued as rs1246904851; called by muse, mutect2, varscan2
- CLCN1 | c.2565G>A p.G855= | Silent (SNP) | VAF 107/299 reads (36%) | catalogued as rs866583816, COSV58368943; called by muse, mutect2, varscan2
- CLGN | c.615C>T p.F205= | Silent (SNP) | VAF 24/187 reads (13%) | catalogued as rs749787516, COSV57774342; called by muse, mutect2, varscan2
- CPE | c.1068C>T p.T356= | Silent (SNP) | VAF 34/257 reads (13%) | catalogued as rs1442814949; called by muse, mutect2, varscan2
- CSPG4 | c.5049C>T p.A1683= | Silent (SNP) | VAF 30/325 reads (9%) | called by muse, mutect2, varscan2
- CYP2C19 | c.300C>T p.F100= | Silent (SNP) | VAF 34/189 reads (18%) | catalogued as rs774817817, COSV64909645; called by muse, mutect2, varscan2
- DAB2IP | c.2415G>A p.Q805= (on ENST00000408936; = p.Q777= on NM_032552.3) | Silent (SNP) | VAF 58/357 reads (16%) | called by muse, mutect2, varscan2
- DACH1 | c.1752C>T p.T584= (on ENST00000619232 / NM_001366712.1; = p.T330= on NM_004392.6) | Silent (SNP) | VAF 31/277 reads (11%) | catalogued as rs757570915; called by muse, mutect2, varscan2
- DACH1 | c.507G>A p.G169= | Silent (SNP) | VAF 52/351 reads (15%) | called by muse, mutect2, varscan2
- DAPK2 | c.765C>T p.S255= | Silent (SNP) | VAF 33/278 reads (12%) | catalogued as rs555502296; called by mutect2, varscan2
- DGKK | c.1089G>A p.V363= | Silent (SNP) | VAF 26/73 reads (36%) | catalogued as COSV65709663; called by muse, mutect2, varscan2
- DMWD | c.1506G>T p.G502= | Silent (SNP) | VAF 62/331 reads (19%) | called by muse, mutect2, varscan2
- DNAH5 | c.2532C>T p.P844= | Silent (SNP) | VAF 47/270 reads (17%) | called by muse, mutect2, varscan2
- DNAH8 | c.12333C>T p.I4111= | Silent (SNP) | VAF 29/235 reads (12%) | catalogued as rs746148886; called by muse, mutect2, varscan2
- DPP3 | c.1743G>A p.E581= | Silent (SNP) | VAF 40/320 reads (13%) | called by muse, mutect2, varscan2
- DYNC1H1 | c.6720A>G p.A2240= | Silent (SNP) | VAF 27/253 reads (11%) | called by muse, mutect2, varscan2
- EBLN1 | c.384C>T p.F128= | Silent (SNP) | VAF 30/236 reads (13%) | called by muse, mutect2, varscan2
- ELFN1 | c.930C>T p.A310= | Silent (SNP) | VAF 55/498 reads (11%) | called by muse, mutect2, varscan2
- FAM71F1 | c.154C>T p.L52= | Silent (SNP) | VAF 127/353 reads (36%) | catalogued as rs528519122; called by muse, mutect2, varscan2
- FAT1 | c.2967G>A p.L989= | Silent (SNP) | VAF 35/306 reads (11%) | called by muse, mutect2, varscan2
- FPR2 | c.327C>T p.L109= | Silent (SNP) | VAF 36/248 reads (15%) | called by muse, varscan2
- GALNT2 | c.354C>T p.I118= | Silent (SNP) | VAF 31/221 reads (14%) | called by muse, mutect2, varscan2
- H1-4 | c.570G>A p.K190= | Silent (SNP) | VAF 33/264 reads (13%) | catalogued as rs1329149804; called by muse, mutect2, varscan2
- HACL1 | c.1623C>T p.S541= | Silent (SNP) | VAF 55/416 reads (13%) | catalogued as COSV58256824; called by muse, mutect2, varscan2
- HARBI1 | c.57C>T p.H19= | Silent (SNP) | VAF 30/239 reads (13%) | catalogued as COSV56319144, COSV56319938; called by muse, mutect2, varscan2
- HMCN1 | c.15105C>T p.I5035= | Silent (SNP) | VAF 26/345 reads (8%) | catalogued as COSV54939079; called by muse, mutect2
- IGHV2-26 | c.282C>T p.T94= | Silent (SNP) | VAF 68/306 reads (22%) | catalogued as rs1555476482; called by muse, mutect2, varscan2
- JPH3 | c.588C>T p.F196= | Silent (SNP) | VAF 43/371 reads (12%) | catalogued as rs747932359, COSV52467894; called by muse, mutect2, varscan2
- KCNK10 | c.1179C>T p.S393= | Silent (SNP) | VAF 51/426 reads (12%) | catalogued as rs775302473, COSV56646847; called by muse, mutect2, varscan2
- KRT79 | c.1068G>A p.R356= | Silent (SNP) | VAF 73/245 reads (30%) | called by muse, mutect2, varscan2
- LDAH | c.69C>T p.T23= | Silent (SNP) | VAF 42/326 reads (13%) | called by muse, mutect2, varscan2
- LNX1 | c.897C>T p.V299= (on ENST00000263925 / NM_001126328.3; = p.V203= on NM_032622.2) | Silent (SNP) | VAF 38/266 reads (14%) | catalogued as COSV55781557; called by muse, mutect2, varscan2
- LRFN2 | c.2259G>A p.T753= | Silent (SNP) | VAF 43/336 reads (13%) | catalogued as rs773172303, COSV57823747, COSV57825855; called by muse, mutect2, varscan2
- LUZP2 | c.930C>T p.I310= | Silent (SNP) | VAF 28/181 reads (15%) | catalogued as rs1422495454, COSV100419390; called by muse, mutect2
- MARCHF1 | c.33C>T p.N11= | Silent (SNP) | VAF 35/247 reads (14%) | catalogued as rs1456325913, COSV56808678; called by muse, mutect2, varscan2
- MICALL2 | c.1860C>T p.A620= | Silent (SNP) | VAF 43/377 reads (11%) | catalogued as rs1047776502, COSV52519890; called by muse, mutect2, varscan2
- MRPS31 | c.450C>T p.P150= | Silent (SNP) | VAF 24/144 reads (17%) | called by muse, mutect2, varscan2
- NPC2 | c.231C>T p.I77= | Silent (SNP) | VAF 36/299 reads (12%) | called by muse, mutect2, varscan2
- NRXN1 | c.390C>T p.I130= | Silent (SNP) | VAF 48/344 reads (14%) | catalogued as COSV67999796; called by muse, mutect2, varscan2
- NUMA1 | c.5133G>A p.E1711= | Silent (SNP) | VAF 48/445 reads (11%) | catalogued as rs777619697; called by muse, mutect2, varscan2
- OR10H3 | c.933C>T p.F311= | Silent (SNP) | VAF 20/109 reads (18%) | catalogued as rs765259784; called by muse, mutect2, varscan2
- OR2G3 | c.906G>A p.R302= | Silent (SNP) | VAF 22/198 reads (11%) | catalogued as COSV60680702; called by muse, mutect2
- OR2W1 | c.294C>T p.I98= | Silent (SNP) | VAF 28/182 reads (15%) | catalogued as COSV101013932; called by muse, mutect2, varscan2
- OR4X2 | c.565C>T p.L189= | Silent (SNP) | VAF 32/274 reads (12%) | called by muse, mutect2, varscan2
- OR51D1 | c.183C>T p.I61= | Silent (SNP) | VAF 57/316 reads (18%) | called by muse, mutect2, varscan2
- OR8D2 | c.93C>T p.F31= | Silent (SNP) | VAF 43/239 reads (18%) | catalogued as rs148447195; called by muse, mutect2, varscan2
- PCDH19 | c.1278C>T p.R426= | Silent (SNP) | VAF 58/213 reads (27%) | catalogued as COSV55259368; called by muse, mutect2, varscan2
- PCDHGA10 | c.675C>T p.L225= | Silent (SNP) | VAF 41/258 reads (16%) | called by muse, mutect2, varscan2
- PIK3C2G | c.3162G>A p.R1054= (on ENST00000676171; = p.R1013= on NM_004570.5) | Silent (SNP) | VAF 24/188 reads (13%) | catalogued as rs372691815; called by muse, mutect2, varscan2
- PKHD1L1 | c.5094C>T p.F1698= | Silent (SNP) | VAF 29/224 reads (13%) | catalogued as COSV65744776; called by muse, mutect2, varscan2
- PRSS36 | c.2343C>T p.L781= | Silent (SNP) | VAF 48/334 reads (14%) | called by muse, mutect2, varscan2
- PTPRB | c.2781C>T p.N927= | Silent (SNP) | VAF 74/242 reads (31%) | catalogued as rs749431250; called by muse, mutect2, varscan2
- PTPRK | c.2220C>T p.I740= (on ENST00000368215 / NM_001291984.2; = p.I741= on NM_002844.4) | Silent (SNP) | VAF 38/240 reads (16%) | called by muse, mutect2, varscan2
- RASA4B | c.390C>T p.A130= | Silent (SNP) | VAF 24/557 reads (4%) | catalogued as rs1205737098; called by muse, mutect2
- RECQL4 | c.825C>T p.V275= | Silent (SNP) | VAF 57/390 reads (15%) | called by muse, mutect2, varscan2
- RNASEL | c.291C>T p.I97= | Silent (SNP) | VAF 30/301 reads (10%) | catalogued as rs776694567, COSV62377953; called by muse, mutect2
- RPP25L | c.432C>T p.S144= | Silent (SNP) | VAF 40/318 reads (13%) | called by muse, mutect2, varscan2
- RTL3 | c.708C>T p.F236= | Silent (SNP) | VAF 53/186 reads (28%) | catalogued as COSV58186020; called by muse, mutect2, varscan2
- SALL4 | c.2145C>T p.I715= | Silent (SNP) | VAF 42/338 reads (12%) | called by muse, mutect2, varscan2
- SCN10A | c.3705G>A p.A1235= | Silent (SNP) | VAF 22/264 reads (8%) | catalogued as rs147376215; ClinVar: likely benign; called by muse, mutect2
- SLC8A3 | c.1767C>T p.F589= | Silent (SNP) | VAF 40/223 reads (18%) | called by muse, mutect2, varscan2
- SLCO1B1 | c.978C>T p.F326= | Silent (SNP) | VAF 27/149 reads (18%) | catalogued as COSV57007664; called by muse, mutect2, varscan2
- SLCO5A1 | c.1488G>A p.L496= | Silent (SNP) | VAF 38/262 reads (15%) | catalogued as COSV52664817; called by muse, mutect2, varscan2
- SMAD6 | c.1161C>T p.I387= | Silent (SNP) | VAF 59/447 reads (13%) | catalogued as rs777669717, COSV56596181; called by muse, mutect2, varscan2
- SMG1 | c.8781C>T p.I2927= | Silent (SNP) | VAF 21/146 reads (14%) | catalogued as rs767813326; called by muse, mutect2, varscan2
- SNX15 | c.237C>T p.F79= | Silent (SNP) | VAF 27/177 reads (15%) | catalogued as rs368357639; called by muse, mutect2, varscan2
- STAMBPL1 | c.372C>T p.D124= | Silent (SNP) | VAF 14/152 reads (9%) | called by muse, mutect2
- TAFA4 | c.237C>T p.F79= | Silent (SNP) | VAF 30/353 reads (8%) | catalogued as COSV55145871; called by muse, mutect2
- TBC1D10C | c.114C>T p.D38= | Silent (SNP) | VAF 54/578 reads (9%) | catalogued as rs776470617; called by muse, mutect2
- TESMIN | c.1299G>A p.T433= | Silent (SNP) | VAF 45/548 reads (8%) | catalogued as rs867073198, COSV54835687, COSV99663274; called by muse, mutect2
- TF | c.2067C>T p.L689= | Silent (SNP) | VAF 13/98 reads (13%) | called by muse, mutect2, varscan2
- TMC5 | c.2958A>G p.E986= (on ENST00000396229 / NM_001105248.1; = p.E740= on NM_024780.5) | Silent (SNP) | VAF 20/194 reads (10%) | called by muse, mutect2, varscan2
- TMCC3 | c.1305C>T p.F435= | Silent (SNP) | VAF 81/313 reads (26%) | catalogued as rs759224978, COSV54153365; called by muse, mutect2, varscan2
- TMPRSS3 | c.258C>T p.I86= | Silent (SNP) | VAF 59/422 reads (14%) | catalogued as rs192083827; called by muse, mutect2, varscan2
- TNXB | c.5553C>T p.F1851= (on ENST00000647633; = p.F1604= on NM_019105.8 and 1 other RefSeq transcript) | Silent (SNP) | VAF 41/232 reads (18%) | catalogued as rs536054720, COSV64476347; called by muse, mutect2, varscan2
- TOP2B | c.1419C>T p.S473= (on ENST00000264331 / NM_001330700.2; = p.S468= on NM_001068.3) | Silent (SNP) | VAF 28/199 reads (14%) | catalogued as rs1305365873; called by muse, mutect2, varscan2
- TRANK1 | c.5286G>A p.K1762= | Silent (SNP) | VAF 32/243 reads (13%) | called by muse, mutect2, varscan2
- TRAV4 | c.243C>T p.I81= | Silent (SNP) | VAF 22/290 reads (8%) | called by muse, mutect2
- TSPEAR | c.726C>T p.I242= | Silent (SNP) | VAF 58/546 reads (11%) | catalogued as rs1555915501; called by muse, mutect2
- TXNDC5 | c.1026C>T p.F342= | Silent (SNP) | VAF 36/257 reads (14%) | catalogued as rs1320177386, COSV51669787; called by muse, mutect2
- UNC13A | c.2016C>T p.S672= | Silent (SNP) | VAF 35/260 reads (13%) | catalogued as rs1467271204; called by muse, mutect2, varscan2
- UNC13C | c.4305C>T p.P1435= | Silent (SNP) | VAF 24/217 reads (11%) | catalogued as rs376495525; called by muse, mutect2, varscan2
- UNC45B | c.1227C>T p.P409= | Silent (SNP) | VAF 29/388 reads (7%) | catalogued as rs1481523440; called by muse, mutect2
- UNC79 | c.7821C>T p.L2607= (on ENST00000393151 / NM_001346218.2; = p.L2430= on NM_020818.5) | Silent (SNP) | VAF 128/506 reads (25%) | called by muse, mutect2, varscan2
- WDFY3 | c.4555T>C p.L1519= | Silent (SNP) | VAF 8/231 reads (3%) | called by muse, mutect2
- ZFHX2 | c.678G>A p.G226= | Silent (SNP) | VAF 93/411 reads (23%) | catalogued as rs1406854888; called by muse, mutect2, varscan2
- ZGRF1 | c.2034C>T p.P678= | Silent (SNP) | VAF 13/177 reads (7%) | called by muse, mutect2
- ZKSCAN3 | c.384G>A p.L128= | Silent (SNP) | VAF 37/182 reads (20%) | called by muse, mutect2, varscan2
- ZNF333 | c.1077C>T p.I359= | Silent (SNP) | VAF 37/284 reads (13%) | catalogued as COSV99468650; called by muse, mutect2, varscan2
- ZNF44 | c.495C>T p.S165= (on ENST00000356109 / NM_001164276.2; = p.S117= on NM_016264.4 and 5 other RefSeq transcripts) | Silent (SNP) | VAF 43/283 reads (15%) | called by muse, mutect2
- ZNF699 | c.885A>G p.T295= | Silent (SNP) | VAF 32/246 reads (13%) | catalogued as rs1244717366; called by muse, varscan2
- ZNF703 | c.1494C>T p.P498= | Silent (SNP) | VAF 91/507 reads (18%) | called by muse, mutect2, varscan2
- ARHGEF4 | c.-295G>A | 5'UTR (SNP) | VAF 25/216 reads (12%) | catalogued as rs1178310406; called by muse, mutect2, varscan2
- CPLANE1 | c.*5494C>T | 3'UTR (SNP) | VAF 20/265 reads (8%) | catalogued as rs578127199, COSV57059861; called by muse, mutect2
- GNAS | chr20:58850764 C>T | 5'Flank (SNP) | VAF 60/456 reads (13%) | catalogued as rs1182143365; called by muse, mutect2, varscan2
- KCNQ1 | c.1394-33690C>T | Intron (SNP) | VAF 19/175 reads (11%) | called by muse, mutect2, varscan2
- KCNQ1 | c.1514+29993C>T | Intron (SNP) | VAF 42/276 reads (15%) | catalogued as rs898585464; called by muse, mutect2, varscan2
- OCIAD1 | c.547+13C>T | Intron (SNP) | VAF 16/168 reads (10%) | called by muse, mutect2
- SCN1B | c.448+348G>A | Intron (SNP) | VAF 22/168 reads (13%) | called by muse, mutect2, varscan2
- SYT7 | c.215+5198G>A | Intron (SNP) | VAF 40/329 reads (12%) | called by muse, mutect2, varscan2
